Somatic mutation profile of tumor specimen TCGA-G9-6369-01A (aliquot TCGA-G9-6369-01A-21D-1961-08) from TCGA case TCGA-G9-6369, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.4 years (20,238 days).
Specimen TCGA-G9-6369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 468a88e8-9627-462f-beb0-d8b900a904ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6369-10A (Blood Derived Normal), aliquot TCGA-G9-6369-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e23e59d4-a607-4ff8-b4c2-cf81cbc7901e

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, In Frame Del 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.391T>G p.W131G | Missense Mutation (SNP) | VAF 86/208 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as rs1057519968, COSV61652911, COSV61653817; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF10 | c.1622A>C p.E541A (on ENST00000398564; = p.E516A on NM_014629.4) | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV50682979; called by muse, mutect2
- ATG14 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as rs761169489, COSV55958465; called by muse, varscan2
- ATOH1 | c.568A>G p.N190D | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.04); catalogued as COSV60038865; called by muse, mutect2, varscan2
- ATP6V1A | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56360764, COSV56365031; called by muse, mutect2, varscan2
- CDC42BPB | c.1386A>C p.Q462H | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV63477116; called by muse, mutect2
- DIP2B | c.4582G>T p.E1528* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV56593072; called by muse, mutect2, varscan2
- FAT3 | c.7291T>C p.Y2431H | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53180799; called by muse, mutect2, varscan2
- ITGA6 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV51274577; called by muse, mutect2, varscan2
- KIN | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV65431590; called by muse, mutect2, varscan2
- MEF2C | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV60925868; called by muse, mutect2, varscan2
- OTOA | c.1474G>A p.V492I (on ENST00000286149; = p.V478I on NM_144672.4) | Missense Mutation (SNP) | VAF 22/317 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs572283930, COSV53764820; called by muse, mutect2
- PTPN2 | c.1009A>G p.M337V | Missense Mutation (SNP) | VAF 142/271 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV58999541; called by muse, mutect2, varscan2
- RLBP1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51529591; called by muse, mutect2, varscan2
- SEC14L5 | c.333C>G p.H111Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.251); catalogued as COSV52042441; called by muse, mutect2, varscan2
- SLC50A1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57596694, COSV57597074; called by muse, mutect2, varscan2
- SOBP | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58003405; called by muse, mutect2
- SYNJ1 | c.782A>C p.N261T | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59157564; called by muse, mutect2, varscan2
- TCAP | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs779699520, COSV54094388; called by muse, mutect2, varscan2
- TMPRSS11D | c.191A>C p.Q64P | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV52226909; called by muse, mutect2
- WAPL | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.681); catalogued as COSV53940690; called by muse, mutect2, varscan2
- SPINK1 | c.214_216del p.L72del | In Frame Del (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- APBA1 | c.732C>T p.G244= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs201766437, COSV55235646; called by muse, mutect2, varscan2
- DGKH | c.1335A>G p.K445= | Silent (SNP) | VAF 40/59 reads (68%) | catalogued as rs202090141, COSV54943065; called by muse, mutect2, varscan2
- EFHC2 | c.126A>G p.G42= | Silent (SNP) | VAF 25/27 reads (93%) | catalogued as COSV69555705; called by muse, mutect2, varscan2
- ROBO1 | c.4011G>A p.E1337= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as COSV71398952; called by muse, mutect2, varscan2
- TBC1D14 | c.855C>T p.D285= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV63391706, COSV63391863; called by muse, mutect2
- KIR3DX1 | n.488C>A | RNA (SNP) | VAF 21/67 reads (31%) | catalogued as COSV55600256, COSV55601526; called by muse, mutect2, varscan2
